EXCEPTIONAL_RESPONDERS case ER-ABEN — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Colon. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a8ad24a0-06a6-498c-8888-7d9283cdea2a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1958; Vital status: Alive.

Diagnoses (1)
1. Small cell carcinoma, NOS: ICD-O-3 morphology code: 8041/3; Tissue or organ of origin: Cecum; Site of resection or biopsy: Cecum; Age at diagnosis: 50.5 years (18,430 days); Year of diagnosis: 2009; AJCC pathologic stage: Stage IV; Prior malignancy: no; Days to last follow up: 1,987 days (5.4 years); Days to best overall response: 237 days; Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Cisplatin; Days to treatment start: 6 days; Days to treatment end: 105 days.
   Treatment given: Therapeutic agents: Etoposide; Days to treatment start: 42 days; Days to treatment end: 107 days.

Follow-up (1 entry)
- Days to follow up: 1,987 days (5.4 years); Disease response: Stable Disease; Progression or recurrence: Yes; Days to recurrence: -2 days; Days progression-free: 1,987 days (5.4 years).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-ABEN-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-ABEN-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 35; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample ER-ABEN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-ABEN-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 10; Percent tumor nuclei: 5; Percent normal cells: 90; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 1.
